Somatic mutation profile of tumor specimen C3N-02637-01 (aliquot CPT0182210007) from CPTAC case C3N-02637, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.5 years (19,558 days).
Specimen C3N-02637-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d41c47ce-fd95-4d60-af2c-eb07171852ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02637-31 (Blood Derived Normal), aliquot CPT0182270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3465ddd7-1aa4-4d2b-82cf-4d7fdf3139be

The open-access MAF lists 9,291 somatic variants for this specimen: 6,549 protein-altering or splice-affecting, 1,708 silent, 1,034 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,596, Silent 1,708, Nonsense Mutation 763, Intron 528, RNA 169, 3'UTR 162, Splice Region 90, Splice Site 80, 5'UTR 75, 5'Flank 57, 3'Flank 42, Frame Shift Del 8.

Variants (750 of 9,291; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6445C>T p.R2149* | Nonsense Mutation (SNP) | VAF 165/509 reads (32%) | catalogued as rs61750654, CM990078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.5497C>T p.R1833* | Nonsense Mutation (SNP) | VAF 58/567 reads (10%) | catalogued as rs137852831, CM980085, COSV55882537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 54/194 reads (28%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 82/302 reads (27%) | catalogued as rs151340621, CM960313, COSV56584423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2
- DEPDC5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as rs772872014, CM146220, COSV56694430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.8010G>A p.W2670* | Nonsense Mutation (SNP) | VAF 73/224 reads (33%) | catalogued as rs1569186252, COSV58889776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.-33C>T | 5'UTR (SNP) | VAF 26/236 reads (11%) | catalogued as rs776176679; ClinVar: pathogenic; called by muse, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 56/175 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ESR1 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as rs1057519714, COSV52784970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852467, CM002001, CM061754, COSV57704780; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F9 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 20/216 reads (9%) | catalogued as rs137852261, CM940671, COSV54378604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 109/333 reads (33%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 71/105 reads (68%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLS | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558973667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPR143 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs62635024, CD951810, CM003027; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HACE1 | c.2242C>T p.R748* | Nonsense Mutation (SNP) | VAF 20/310 reads (6%) | catalogued as rs869025281, CM1512806, COSV53502635; ClinVar: pathogenic; called by muse, mutect2
- HADHA | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 124/338 reads (37%) | catalogued as rs147103714, CM107604, COSV101024219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 77/297 reads (26%) | catalogued as rs267606866, CM103331, COSV65181961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IL2RG | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs111033618, CM950692; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518621, COSV65565954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 73/427 reads (17%) | catalogued as rs17215500, CM057185, CM992171; ClinVar: pathogenic / benign / uncertain significance; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 32/285 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KLHL41 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); catalogued as rs730882260, CM1312342, COSV52929638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.13645C>T p.R4549C | Missense Mutation (SNP) | VAF 34/315 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51276981, COSV51294405; called by muse, mutect2, varscan2
- LAMA1 | c.8931G>A p.W2977* | Nonsense Mutation (SNP) | VAF 22/534 reads (4%) | catalogued as rs1236564978; ClinVar: pathogenic; called by muse, mutect2
- LDLR | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 170/665 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.244); catalogued as rs551747280, CM127521; ClinVar: likely benign / likely pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 37/338 reads (11%) | catalogued as rs1238694184, CM060375, COSV51278193; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYF5 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 124/442 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565864693, COSV57355718; ClinVar: pathogenic; called by muse, varscan2
- NF1 | c.2325+2T>C p.X775_splice | Splice Site (SNP) | VAF 98/292 reads (34%) | catalogued as rs1567847972, CS030991, CS1512928, COSV62229047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 202/555 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs80358258, CM012441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6559C>T p.R2187* | Nonsense Mutation (SNP) | VAF 24/216 reads (11%) | catalogued as rs587784209, CM052337, COSV61774501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs863224147, CM961098, COSV58825380, COSV58827746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3128T>C p.M1043T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1057519937, COSV55900332; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, mutect2, varscan2
- PLA2G4A | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434635, CM081744, COSV66556272; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLCB4 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514482, CM123398, COSV53801196, COSV99595451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 82/302 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 240/363 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RLIM | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1569309460, COSV60325321; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETBP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 11/231 reads (5%) | catalogued as rs1568234874, COSV56319931; ClinVar: pathogenic; called by muse, mutect2
- SLC4A1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 32/370 reads (9%) | catalogued as rs750930293, CM1212125, COSV52258614; ClinVar: pathogenic; called by muse, mutect2
- SMARCD1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57317934, COSV57318902; called by muse, mutect2, varscan2
- TGFBR2 | c.1397-1G>A p.X466_splice | Splice Site (SNP) | VAF 126/441 reads (29%) | catalogued as rs1553631693, CS064462, COSV55464532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMC1 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 53/146 reads (36%) | catalogued as rs121908073, CM020519, COSV99918783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMCO1 | c.616C>T p.R206* (on ENST00000612311 / NM_001256164.1; = p.R155* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 61/260 reads (23%) | catalogued as rs765379963, COSV100903179, COSV63319044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 159/690 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs727504275, CM050764, COSV52571327, COSV52572563; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UNC80 | c.5671C>T p.R1891* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs1262654975, COSV55886621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.12151G>T p.E4051* | Nonsense Mutation (SNP) | VAF 71/183 reads (39%) | catalogued as rs1262416703, COSV56406078; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.5395C>T p.R1799* | Nonsense Mutation (SNP) | VAF 58/181 reads (32%) | catalogued as rs1555933937, COSV61073632; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.7603C>T p.R2535* | Nonsense Mutation (SNP) | VAF 32/374 reads (9%) | catalogued as rs386834107, CM041277, COSV62134139; ClinVar: likely pathogenic; called by muse, mutect2
- WDR35 | c.1415G>A p.R472Q (on ENST00000345530 / NM_001006657.2; = p.R461Q on NM_020779.4) | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs200140363, COSV55601925, COSV99852911; ClinVar: likely pathogenic; called by muse, varscan2
- XDH | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 57/513 reads (11%) | catalogued as rs119460972, CM971597, COSV101052504, COSV65151007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A2M | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs199960398; called by muse, mutect2, varscan2
- A2ML1 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100229626; called by muse, mutect2, varscan2
- AAAS | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 196/641 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752732620; called by muse, mutect2, varscan2
- AADACL4 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs777591284, COSV66105921; called by muse, mutect2, varscan2
- AADAT | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61786973; called by muse, mutect2, varscan2
- AAR2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs375291820; called by muse, mutect2, varscan2
- AARD | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373101045; called by mutect2, varscan2
- AATK | c.2978G>A p.R993Q (on ENST00000326724 / NM_001080395.3; = p.R890Q on NM_004920.2) | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370391415; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA13 | c.2315C>A p.S772Y | Missense Mutation (SNP) | VAF 28/467 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1177467637, COSV101329949; called by muse, mutect2
- ABCA13 | c.2452A>C p.N818H | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.971); catalogued as rs770924059; called by muse, mutect2, varscan2
- ABCA13 | c.9464C>T p.S3155F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV71292416; called by muse, mutect2, varscan2
- ABCA4 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs548888187, COSV64672582; called by muse, mutect2, varscan2
- ABCA4 | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs1448232035; called by muse, mutect2, varscan2
- ABCA5 | c.4789G>T p.E1597* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as COSV52220912; called by muse, mutect2, varscan2
- ABCB10 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs200713703; called by muse, mutect2
- ABCB11 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1030004521, COSV99793428; called by muse, mutect2
- ABCB5 | c.3097C>A p.L1033I (on ENST00000404938 / NM_001163941.2; = p.L588I on NM_178559.6) | Missense Mutation (SNP) | VAF 111/581 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51721696; called by muse, mutect2, varscan2
- ABCB8 | c.2113G>A p.E705K (on ENST00000297504 / NM_001282291.2; = p.E688K on NM_007188.5) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs1325175450, COSV52502181; called by muse, mutect2, varscan2
- ABCC1 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs201585228, COSV60689144; called by muse, mutect2, varscan2
- ABCC2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs748245551, COSV64970648, COSV64970740; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 63/432 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2, varscan2
- ABCC4 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs771698317, COSV65318332; called by muse, mutect2, varscan2
- ABCC4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV65318924; called by muse, mutect2
- ABCC6 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs923888648; called by muse, mutect2, varscan2
- ABCC8 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758995284, COSV56858022; called by muse, mutect2, varscan2
- ABCD1 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 76/429 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.187); catalogued as rs782567454, CM120982, COSV54387666; called by muse, mutect2, varscan2
- ABHD10 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV56325747; called by muse, varscan2
- ABI3BP | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs553697655, COSV52528518; called by muse, mutect2, varscan2
- ABL2 | c.1508G>A p.R503Q (on ENST00000502732 / NM_007314.4; = p.R488Q on NM_005158.5) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178157504, COSV61018314; called by muse, mutect2, varscan2
- ABRAXAS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as rs1300270870, COSV55029469; called by muse, mutect2, varscan2
- AC004593.2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 94/215 reads (44%) | catalogued as rs555946730; called by muse, mutect2, varscan2
- AC011005.1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 180/347 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs757190044, COSV71955851; called by muse, mutect2, varscan2
- AC011005.1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs531038347; called by muse, mutect2
- AC011455.2 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 94/889 reads (11%) | catalogued as rs761616100; called by muse, mutect2, varscan2
- AC024940.1 | n.3726G>A | Splice Region (SNP) | VAF 36/123 reads (29%) | catalogued as rs559550557; called by muse, mutect2, varscan2
- AC069544.2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.18); catalogued as rs1221332115; called by muse, mutect2, varscan2
- AC069544.2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs1031806095; called by muse, mutect2, varscan2
- AC126283.2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350193194, COSV67098235; called by muse, mutect2, varscan2
- AC126283.2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs143366614, CM1311019; ClinVar: benign; called by muse, mutect2, varscan2
- ACAA2 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs1322908376; called by muse, mutect2, varscan2
- ACACA | c.7103G>A p.R2368Q | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs766921857; called by muse, mutect2, varscan2
- ACACA | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769240769; called by muse, mutect2, varscan2
- ACACB | c.4821C>T p.I1607= | Splice Region (SNP) | VAF 36/120 reads (30%) | catalogued as rs776234149, COSV58128696; called by muse, mutect2, varscan2
- ACACB | c.6719G>A p.R2240Q | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs773800691, COSV58139408; called by muse, mutect2, varscan2
- ACAD10 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs775196004; called by muse, mutect2, varscan2
- ACAD11 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768617080, COSV53899123; called by mutect2, varscan2
- ACADSB | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1266747835, COSV62550543; called by muse, mutect2, varscan2
- ACAP1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs767071679, COSV50138819; called by mutect2, varscan2
- ACCSL | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs752690708; called by mutect2, varscan2
- ACER1 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781481589; called by muse, mutect2, varscan2
- ACHE | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs945898681, COSV53818068; called by muse, mutect2, varscan2
- ACKR2 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56180581; called by muse, mutect2, varscan2
- ACO1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143245103; called by muse, mutect2, varscan2
- ACOD1 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.837); catalogued as rs1490745448; called by muse, mutect2, varscan2
- ACOT13 | c.305T>G p.I102S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs772944032; called by muse, mutect2, varscan2
- ACP1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 155/487 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs768955905; called by muse, mutect2, varscan2
- ACSL1 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs768759701, COSV55664441; called by muse, mutect2, varscan2
- ACSL4 | c.2014C>T p.R672* (on ENST00000340800 / NM_022977.2; = p.R631* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV61613889; called by muse, mutect2, varscan2
- ACSM2A | c.253G>T p.E85* (on ENST00000219054; = p.E6* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 75/351 reads (21%) | catalogued as COSV54590263, COSV99525659; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACSM4 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs771329876; called by muse, mutect2, varscan2
- ACSM5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.263); catalogued as rs530105948, COSV100088604, COSV59369492; called by mutect2, varscan2
- ACSS2 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs754546126, COSV99489865; called by muse, mutect2, varscan2
- ACSS3 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs973982422; called by mutect2, varscan2
- ACTN2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 159/573 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs559395092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR2B | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs777404502; called by muse, mutect2, varscan2
- ACY3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs768583318, COSV54828438; called by muse, mutect2, varscan2
- ADA2 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.048); catalogued as COSV52832414; called by muse, mutect2, varscan2
- ADAD2 | c.552G>T p.E184D (on ENST00000315906 / NM_001145400.2; = p.E256D on NM_139174.4) | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV51894994; called by muse, mutect2, varscan2
- ADAM11 | c.1323C>T p.L441= | Splice Region (SNP) | VAF 72/201 reads (36%) | catalogued as rs765158980; called by muse, mutect2, varscan2
- ADAM11 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52346907; called by muse, mutect2
- ADAM12 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs376021623; called by muse, mutect2, varscan2
- ADAM17 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs780293025; called by mutect2, varscan2
- ADAM18 | c.1915T>G p.F639V | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs759268867, COSV99695358; called by muse, mutect2, varscan2
- ADAM20 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.392); catalogued as rs754605627; called by muse, mutect2, varscan2
- ADAM28 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV56103607; called by muse, mutect2, varscan2
- ADAMTS1 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs917144750; called by muse, mutect2, varscan2
- ADAMTS13 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 213/642 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs1048590351; called by muse, mutect2, varscan2
- ADAMTS13 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782272645, COSV63020869; called by muse, mutect2, varscan2
- ADAMTS19 | c.1615C>A p.L539I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50745607; called by muse, mutect2, varscan2
- ADAMTS20 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV67130027; called by muse, mutect2, varscan2
- ADAMTS3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs768336339, COSV54391795; called by muse, mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as rs777065435, COSV53177958; called by muse, mutect2, varscan2
- ADAMTS6 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.804); catalogued as rs569886769, COSV66859135; called by mutect2, varscan2
- ADAMTS7 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs3825828, COSV66306973, COSV66309919; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2996G>A p.S999N | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs757703540; called by muse, varscan2
- ADAP2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as rs199866282, COSV58294906; called by muse, mutect2, varscan2
- ADCY8 | c.1729C>A p.L577M | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53912655; called by muse, mutect2, varscan2
- ADCY9 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53572158; called by muse, mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by muse, mutect2, varscan2
- ADD1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs531177121; called by muse, mutect2, varscan2
- ADD1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142283650; called by muse, varscan2
- ADD1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766033361, COSV53267490; called by muse, varscan2
- ADD2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.129); catalogued as rs114311724; called by muse, mutect2, varscan2
- ADD2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558526530, COSV52456622, COSV52462275; called by muse, mutect2, varscan2
- ADGRB3 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV53240014; called by muse, mutect2, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2, varscan2
- ADGRE3 | c.1445C>A p.S482Y | Missense Mutation (SNP) | VAF 167/340 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53728652; called by muse, mutect2, varscan2
- ADGRE3 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99506474; called by muse, mutect2, varscan2
- ADGRF4 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs767991215; called by muse, mutect2, varscan2
- ADGRG2 | c.2366C>T p.T789M (on ENST00000379869 / NM_001079858.3; = p.T786M on NM_005756.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780666105, COSV61338004; called by mutect2, varscan2
- ADGRV1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs876657822, COSV67979033; ClinVar: uncertain significance; called by muse, mutect2
- ADGRV1 | c.13159C>T p.R4387C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs770485484, COSV67985727; called by muse, mutect2, varscan2
- ADH7 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs759568380, COSV52920929; called by muse, mutect2, varscan2
- ADNP2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV104384863; called by muse, mutect2, varscan2
- ADPRH | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 59/517 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780404094; called by muse, mutect2, varscan2
- ADPRH | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs150984649, COSV63695504; called by muse, mutect2, varscan2
- ADPRHL1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 58/214 reads (27%) | catalogued as rs1463128417; called by muse, mutect2, varscan2
- ADRA2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787168; called by muse, varscan2
- ADRA2B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337347; called by muse, varscan2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | catalogued as rs753451653, COSV100321078; called by muse, mutect2, varscan2
- AFG1L | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs780355805; called by muse, mutect2, varscan2
- AGBL1 | c.1559G>T p.R520I | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as COSV66856573; called by muse, mutect2, varscan2
- AGBL2 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as COSV54093593; called by muse, mutect2, varscan2
- AGBL3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as rs998810279; called by muse, varscan2
- AGK | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780744663, COSV62594437; called by muse, mutect2, varscan2
- AGL | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 39/306 reads (13%) | catalogued as COSV99648143; called by muse, mutect2, varscan2
- AGL | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 47/149 reads (32%) | catalogued as COSV54054022; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 20/199 reads (10%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AHCYL1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1265315243, COSV63208875; called by muse, mutect2, varscan2
- AHNAK | c.13976A>C p.K4659T | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57222685; called by muse, mutect2, varscan2
- AHNAK2 | c.16035G>T p.E5345D | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as COSV100316795; called by muse, mutect2, varscan2
- AHNAK2 | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 151/479 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1442280714; called by muse, mutect2, varscan2
- AHR | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54125879; called by muse, mutect2, varscan2
- AIM2 | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV63698904; called by muse, mutect2, varscan2
- AJM1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1365712477; called by muse, mutect2, varscan2
- AK7 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs758921408, COSV50869348, COSV50870311; called by muse, mutect2, varscan2
- AK9 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58143321; called by muse, mutect2, varscan2
- AKAIN1 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV101439847; called by muse, mutect2, varscan2
- AKAP12 | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99483199; called by muse, mutect2, varscan2
- AKAP17A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as rs768019796, COSV58308662; called by muse, mutect2
- AKAP3 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57414298; called by muse, mutect2, varscan2
- AKAP4 | c.1401C>A p.F467L | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100654350; called by muse, mutect2, varscan2
- AKAP9 | c.10516C>A p.L3506I (on ENST00000359028; = p.L3482I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62350106; called by muse, mutect2, varscan2
- AKNA | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200965180; called by muse, mutect2, varscan2
- AKR1E2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs143113841; called by muse, mutect2
- AKT1S1 | c.487G>A p.G163S (on ENST00000344175 / NM_001098633.4; = p.G183S on NM_032375.5) | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as rs1403989698, COSV100465437; called by muse, mutect2, varscan2
- AKT3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99794554; called by muse, mutect2, varscan2
- AL121899.2 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1331369046; called by muse, mutect2
- AL645922.1 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745794224, CM103422, COSV54960081; called by muse, mutect2
- AL645922.1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as rs141965248; called by muse, mutect2, varscan2
- ALCAM | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1448199395, COSV60250831; called by muse, mutect2, varscan2
- ALDH1A1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV52789403; called by muse, mutect2, varscan2
- ALDH1L2 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as COSV51558053; called by muse, mutect2, varscan2
- ALDH3B1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs575081185; called by muse, mutect2, varscan2
- ALDH5A1 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs757187379; called by muse, varscan2
- ALG11 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200166628; called by muse, mutect2, varscan2
- ALG11 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201526759, COSV73000831; called by muse, mutect2, varscan2
- ALG13 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV52644769; called by muse, mutect2, varscan2
- ALG14 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs754944986, COSV64636201; called by muse, mutect2, varscan2
- ALG6 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 82/259 reads (32%) | catalogued as COSV54763161; called by muse, mutect2, varscan2
- ALK | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs754214919, COSV66557243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 44/333 reads (13%) | catalogued as COSV101202339; called by muse, mutect2, varscan2
- ALKBH6 | c.448G>T p.E150* (on ENST00000252984 / NM_001297701.2; = p.E178* on NM_032878.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs758745205, COSV53323967, COSV53324364; called by muse, mutect2, varscan2
- ALOX12B | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100046894; called by muse, mutect2, varscan2
- ALPK2 | c.3677G>T p.R1226I | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV64498175; called by muse, mutect2, varscan2
- AMACR | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 57/220 reads (26%) | catalogued as COSV56869842, COSV99672137; called by muse, mutect2, varscan2
- AMER3 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766058210; called by muse, varscan2
- AMER3 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs369274817, COSV58466725; called by muse, varscan2
- AMER3 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as rs1055694945; called by muse, mutect2, varscan2
- AMFR | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs552799092; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMN1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV55671289; called by muse, mutect2, varscan2
- AMOTL1 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 130/407 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs901646322; called by muse, mutect2, varscan2
- AMPD3 | c.8G>A p.R3Q (on ENST00000396553 / NM_001025389.2; = p.R12Q on NM_000480.3) | Missense Mutation (SNP) | VAF 34/653 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as rs1363572849, COSV67329809, COSV99074121; called by muse, mutect2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2
- ANAPC1 | c.4948G>T p.E1650* | Nonsense Mutation (SNP) | VAF 110/466 reads (24%) | catalogued as rs749616796, COSV100595215, COSV61978888; called by muse, mutect2, varscan2
- ANAPC1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1288534326, COSV100594686, COSV61974363; called by muse, mutect2, varscan2
- ANAPC2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs775462838; called by muse, mutect2, varscan2
- ANGPT2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | catalogued as COSV100291184; called by muse, mutect2, varscan2
- ANK1 | c.4187C>A p.S1396Y | Missense Mutation (SNP) | VAF 48/592 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55876878, COSV55899084; called by muse, mutect2
- ANK2 | c.9172C>T p.R3058C | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs188282049, COSV52157886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.6658C>A p.Q2220K | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as COSV55083277; called by mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKAR | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1310840138; called by muse, varscan2
- ANKAR | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99854581; called by muse, varscan2
- ANKFY1 | c.2237G>A p.R746H (on ENST00000341657 / NM_001330063.2; = p.R747H on NM_016376.5) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs762073269, COSV58918602, COSV58920120; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs949524880, COSV51841395; called by muse, mutect2, varscan2
- ANKIB1 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs752059649; called by muse, mutect2, varscan2
- ANKRD11 | c.2518C>T p.R840W | Missense Mutation (SNP) | VAF 117/379 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761259443, CD162073, COSV56363768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.2100T>G p.F700L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100041093; called by muse, mutect2, varscan2
- ANKRD12 | c.5456C>A p.S1819Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50819436; called by muse, mutect2
- ANKRD13A | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 71/233 reads (30%) | catalogued as rs768945364; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62006674; called by muse, mutect2
- ANKRD22 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64236222; called by muse, mutect2, varscan2
- ANKRD24 | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as COSV53670196; called by muse, mutect2, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as COSV67516849; called by muse, mutect2, varscan2
- ANKRD33B | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1358224167; called by muse, mutect2
- ANKRD33B | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs750557599, COSV56982003; called by muse, mutect2
- ANKRD34C | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1490294400; called by muse, mutect2, varscan2
- ANKRD40 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 38/166 reads (23%) | catalogued as COSV53335376; called by muse, mutect2, varscan2
- ANKRD44 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs780836038, COSV99984889; called by muse, mutect2, varscan2
- ANKS1A | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527425948; called by muse, mutect2, varscan2
- ANLN | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs752000697, COSV56078873; called by muse, mutect2
- ANO3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1161758979, COSV56785162; called by muse, mutect2
- ANO4 | c.851G>A p.R284H (on ENST00000392977 / NM_001286615.2; = p.R249H on NM_178826.4) | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1185072123, COSV54597554; called by muse, varscan2
- ANO4 | c.2143G>T p.E715* (on ENST00000392977 / NM_001286615.2; = p.E680* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100153723; called by muse, mutect2
- ANO6 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755797821, COSV57668467; called by muse, mutect2, varscan2
- ANO7 | c.445C>T p.R149C (on ENST00000274979; = p.R94C on NM_001001666.4) | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs763945681, COSV51467841; called by muse, mutect2, varscan2
- ANOS1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 127/387 reads (33%) | catalogued as CM015286; called by muse, mutect2, varscan2
- ANP32D | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99874225; called by muse, mutect2, varscan2
- ANPEP | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs375782169; called by muse, mutect2, varscan2
- ANXA6 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as rs576940712; called by muse, mutect2, varscan2
- AOX1 | c.2534C>A p.T845N | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1340186102; called by muse, mutect2, varscan2
- AP2B1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 17/190 reads (9%) | catalogued as rs1231191557, COSV51999278; called by muse, mutect2
- AP3S2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 56/180 reads (31%) | catalogued as COSV60517872; called by muse, mutect2, varscan2
- APBA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV101258120, COSV101258206; called by muse, mutect2, varscan2
- APBA3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 161/346 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs762279560, COSV57462429; called by muse, mutect2, varscan2
- APC | c.7391C>A p.S2464Y | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766473931, COSV57326479, COSV57388076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.3992G>A p.R1331H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs962278969, COSV52019476; called by muse, mutect2
- APEH | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs779678983, COSV56531982; called by muse, mutect2, varscan2
- APOBEC3B | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.481); catalogued as COSV100213777; called by muse, mutect2, varscan2
- APOL5 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as rs558909936; called by muse, mutect2, varscan2
- APP | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV60998162, COSV60998764; called by mutect2, varscan2
- AQP11 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332997380; called by muse, mutect2, varscan2
- ARAF | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51692926; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2
- ARAP3 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779869242; called by muse, mutect2, varscan2
- ARFGAP1 | c.775-6G>A | Splice Region (SNP) | VAF 70/233 reads (30%) | catalogued as rs752877009; called by muse, varscan2
- ARFGEF1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200392828, COSV51620792; called by muse, mutect2, varscan2
- ARFGEF1 | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1423653976; called by muse, mutect2, varscan2
- ARGLU1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.947); catalogued as COSV101033654; called by muse, mutect2, varscan2
- ARHGAP15 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99714173; called by muse, mutect2, varscan2
- ARHGAP17 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs775863425, COSV51507886; called by muse, mutect2, varscan2
- ARHGAP19 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765513484, COSV57392233; called by muse, mutect2, varscan2
- ARHGAP20 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99503255; called by muse, mutect2, varscan2
- ARHGAP21 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs771305026, COSV100256084; called by muse, mutect2, varscan2
- ARHGAP24 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67837028; called by muse, mutect2, varscan2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 35/277 reads (13%) | catalogued as COSV51987040; called by muse, mutect2, varscan2
- ARHGAP29 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748894382, COSV53110021; called by muse, mutect2, varscan2
- ARHGAP30 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV63515710; called by muse, mutect2, varscan2
- ARHGAP32 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776079368, COSV59845539; called by muse, mutect2, varscan2
- ARHGAP35 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs982301676, COSV101351599; called by muse, mutect2, varscan2
- ARHGAP9 | c.1846C>T p.R616W (on ENST00000393797 / NM_001319850.2; = p.R597W on NM_032496.4) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs747924330; called by muse, mutect2, varscan2
- ARHGEF10 | c.2470C>T p.R824* (on ENST00000398564; = p.R799* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 100/442 reads (23%) | catalogued as rs1297695311, COSV50653121; called by muse, mutect2, varscan2
- ARHGEF10 | c.4075G>A p.V1359I (on ENST00000398564; = p.V1334I on NM_014629.4) | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs748072321; called by muse, mutect2, varscan2
- ARHGEF11 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766437692; called by muse, varscan2
- ARHGEF25 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs199891478; called by muse, mutect2, varscan2
- ARHGEF33 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs1349767300; called by muse, varscan2
- ARHGEF39 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV58397349; called by muse, mutect2
- ARHGEF7 | c.434G>A p.R145Q (on ENST00000375741 / NM_001113511.2; = p.R124Q on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as rs764281725, COSV54544045; called by muse, mutect2, varscan2
- ARHGEF7 | c.2318G>A p.R773H (on ENST00000646102 / NM_001354046.1; = p.R557H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs958551589; called by muse, mutect2, varscan2
- ARID2 | c.4241G>T p.R1414I | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs146518146, COSV57602936, COSV57612118; called by muse, mutect2, varscan2
- ARID4A | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | catalogued as rs1344759651, COSV62162823; called by muse, mutect2, varscan2
- ARID5B | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as rs1423129750; called by muse, mutect2, varscan2
- ARIH1 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.553); catalogued as COSV65911005; called by muse, mutect2, varscan2
- ARIH1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs1454157851; called by muse, mutect2, varscan2
- ARL10 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs1392810335, COSV53799876; called by muse, mutect2
- ARMC1 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs774241744; called by muse, mutect2
- ARMC4 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV59462522; called by muse, mutect2, varscan2
- ARMCX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs781783235, COSV57529674; called by muse, mutect2, varscan2
- ARMCX2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs782787106; called by muse, mutect2, varscan2
- ARMCX6 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs782200072; called by muse, mutect2, varscan2
- ARNTL2 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs911421382, COSV53824639, COSV99667957; called by muse, varscan2
- ARPIN | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs906002880, COSV104422960; called by muse, mutect2, varscan2
- ARPP21 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | catalogued as COSV51809301; called by muse, mutect2, varscan2
- ARRB2 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 108/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346973; called by muse, mutect2, varscan2
- ARRDC2 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV104382072; called by muse, mutect2
- ARSG | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs754703816, COSV50929623; called by muse, mutect2, varscan2
- ARSL | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 186/532 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776323240, COSV66964826; called by muse, mutect2, varscan2
- ART3 | c.1166T>C p.L389P (on ENST00000355810 / NM_001377173.1; = p.L378P on NM_001179.6) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs778762393; called by muse, mutect2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100727209; called by muse, mutect2
- ASAP2 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.786); catalogued as COSV55633037; called by muse, mutect2, varscan2
- ASB2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 181/559 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs767854646; called by muse, mutect2, varscan2
- ASB3 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs371519069; called by muse, mutect2, varscan2
- ASB4 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1199376893; called by muse, mutect2
- ASB5 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as rs534160855, COSV56671180; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by mutect2, varscan2
- ASCC3 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61234643; called by muse, mutect2
- ASH1L | c.8867G>A p.R2956Q (on ENST00000368346 / NM_001366177.2; = p.R2951Q on NM_018489.3) | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs756414058, COSV64206037; called by muse, mutect2, varscan2
- ASH1L | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758885213, COSV64205321; called by muse, mutect2, varscan2
- ASIC1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1433067923, COSV57316584; called by muse, mutect2, varscan2
- ASIC5 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs144591256; called by muse, varscan2
- ASPM | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200681905, COSV54139741, COSV99660913; called by muse, mutect2, varscan2
- ASPM | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs1227283442, COSV99659125; called by muse, mutect2
- ASTN2 | c.1355G>A p.G452D (on ENST00000313400 / NM_001365069.1; = p.G401D on NM_014010.5) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV57753585; called by muse, mutect2, varscan2
- ASXL1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370054224; called by muse, mutect2, varscan2
- ASZ1 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497723; called by muse, mutect2, varscan2
- ATAD2B | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 56/173 reads (32%) | catalogued as rs1324537078, COSV99477585; called by muse, mutect2, varscan2
- ATG101 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs529183008, COSV100400980; called by muse, mutect2, varscan2
- ATG16L1 | c.1769C>T p.S590L (on ENST00000392017 / NM_030803.7; = p.S571L on NM_017974.4) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs779928715, COSV100731253, COSV100731365; called by muse, mutect2, varscan2
- ATG4A | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58965934; called by muse, mutect2, varscan2
- ATG4C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs759584462, COSV58606506; called by muse, mutect2, varscan2
- ATM | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1445292591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.3871C>A p.L1291I | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV53763520; called by muse, mutect2, varscan2
- ATM | c.4255C>A p.L1419I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53761365; called by muse, varscan2
- ATM | c.8435C>A p.S2812Y | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as CD162053, COSV53734098; called by muse, mutect2, varscan2
- ATP10A | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs747360622, COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- ATP10D | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99905559; called by muse, mutect2, varscan2
- ATP11A | c.3142C>A p.L1048I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV52108617; called by muse, mutect2, varscan2
- ATP11B | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995122602, COSV60028906; called by muse, mutect2, varscan2
- ATP11C | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs147128476, COSV100557301, COSV59568659, COSV59576357; called by muse, mutect2, varscan2
- ATP13A1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs763096515, COSV52284614; called by muse, mutect2, varscan2
- ATP13A3 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs531855588, COSV55462596; called by muse, mutect2, varscan2
- ATP13A4 | c.2025G>A p.T675= | Splice Region (SNP) | VAF 108/358 reads (30%) | catalogued as rs200015919; called by muse, mutect2, varscan2
- ATP1A2 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 178/566 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs868105479; called by muse, varscan2
- ATP1A4 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755473222, COSV63627384, COSV63627420; called by muse, mutect2, varscan2
- ATP2A2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 128/363 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757914881, CM113597; called by muse, mutect2, varscan2
- ATP2B4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141117629; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP4A | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as rs779336531, COSV52871425, COSV52872555; called by muse, mutect2
- ATP6V1B1 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV52272851; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM155738; called by muse, mutect2, varscan2
- ATP6V1FNB | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs764489700; called by muse, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- ATP8A2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 32/150 reads (21%) | catalogued as COSV54943466, COSV99683072; called by muse, mutect2, varscan2
- ATP8A2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200573494, COSV54938064; called by muse, mutect2, varscan2
- ATP8B1 | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 134/416 reads (32%) | catalogued as rs369054652, CM043833; called by muse, mutect2, varscan2
- ATP8B4 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52708947; called by muse, mutect2, varscan2
- ATRX | c.5450G>A p.R1817K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100970167; called by muse, mutect2, varscan2
- ATRX | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64877060, COSV64882414; called by muse, mutect2, varscan2
- ATRX | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV64875018; called by muse, mutect2, varscan2
- ATXN3 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as rs1408380347, COSV61493414; called by muse, mutect2
- ATXN3L | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376294771, COSV66075374; called by muse, mutect2, varscan2
- ATXN3L | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 11/178 reads (6%) | catalogued as rs1252801787, COSV101019398, COSV66075342; called by muse, mutect2
- AVL9 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378455700; called by muse, mutect2
- AXDND1 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as rs772723024, COSV100858277, COSV100858455; called by muse, mutect2, varscan2
- AXIN2 | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 194/488 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1064795595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AZIN1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1316801091; called by muse, mutect2, varscan2
- B3GALNT1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs752083614, COSV57581127; called by muse, mutect2, varscan2
- B3GLCT | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 55/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769182025; called by muse, mutect2, varscan2
- B3GNT2 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV100114059; called by muse, mutect2, varscan2
- B3GNTL1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1224670800, COSV57948261; called by muse, mutect2, varscan2
- B4GALNT2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100302393; called by muse, mutect2, varscan2
- BAALC | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs1226874301; called by muse, mutect2
- BACE1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs371130142; called by muse, mutect2, varscan2
- BAG5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs757492335, COSV54570293; called by muse, mutect2, varscan2
- BAHCC1 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 105/332 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs782680282; called by muse, mutect2, varscan2
- BAIAP2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs766633674, COSV58338283; called by muse, mutect2, varscan2
- BAIAP2L1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs373903465; called by muse, mutect2
- BAIAP2L1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368033137; called by muse, mutect2, varscan2
- BARHL1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV55038359; called by muse, mutect2, varscan2
- BAZ2B | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs373486810; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, mutect2, varscan2
- BBS9 | c.797G>T p.R266I | Missense Mutation (SNP) | VAF 218/463 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54174522; called by muse, mutect2, varscan2
- BBX | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748575488; called by muse, mutect2, varscan2
- BCAS3 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as rs1321744067, COSV66777239; called by muse, mutect2, varscan2
- BCAT2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 108/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767653663, CM159649, COSV60273628; called by muse, mutect2, varscan2
- BCCIP | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 26/210 reads (12%) | catalogued as COSV99532851; called by muse, mutect2, varscan2
- BCKDK | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs553956491, COSV54893477; called by muse, mutect2, varscan2
- BCOR | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 173/494 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60707916; called by muse, mutect2, varscan2
- BCOR | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 140/495 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV60721782; called by muse, mutect2, varscan2
- BCORL1 | c.3661C>A p.L1221M | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500235; called by muse, mutect2, varscan2
- BDKRB2 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314751517; called by muse, mutect2, varscan2
- BDP1 | c.4988T>G p.I1663S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs759497798; called by muse, mutect2
- BEND5 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65718687; called by muse, mutect2, varscan2
- BEST3 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV56995104; called by muse, mutect2
- BFSP1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100925453; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2
- BICD2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs571839806, COSV63549918; called by muse, mutect2, varscan2
- BICRA | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as rs1470890154; called by muse, mutect2, varscan2
- BIN3 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.142); catalogued as rs373328617; called by muse, mutect2
- BIRC2 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 11/140 reads (8%) | catalogued as COSV104390356; called by muse, mutect2
- BLVRA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs138692014; called by muse, mutect2, varscan2
- BMP15 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs782369768; called by muse, mutect2, varscan2
- BMP7 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs202153108; called by muse, mutect2, varscan2
- BMPER | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 149/635 reads (23%) | catalogued as rs1241251519; called by muse, mutect2, varscan2
- BNC1 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61757287; called by muse, mutect2, varscan2
- BNC2 | c.2012G>A p.S671N | Missense Mutation (SNP) | VAF 135/424 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs754044392; called by muse, mutect2, varscan2
- BOD1L1 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs552554656; called by muse, mutect2, varscan2
- BOD1L1 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772980975, COSV50062216; called by muse, mutect2, varscan2
- BRCA2 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM980234; called by muse, mutect2, varscan2
- BRCA2 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs80358842, CM101422, COSV66450746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7651A>C p.K2551Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs398122587; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRD3 | c.395T>G p.I132S | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100325749; called by muse, mutect2, varscan2
- BRD8 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs771114782, COSV54723871; called by muse, mutect2, varscan2
- BRDT | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as COSV62863553; called by muse, varscan2
- BRDT | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62864021, COSV62864626; called by muse, varscan2
- BRINP1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as rs1043377, COSV56291420; called by muse, mutect2, varscan2
- BRINP3 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201165374, COSV66513018, COSV66537847; called by muse, mutect2, varscan2
- BRPF1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778333888, COSV57403882; called by muse, mutect2, varscan2
- BRSK1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 234/482 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs201425077; called by muse, mutect2, varscan2
- BRWD3 | c.4586G>A p.R1529Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs778419234, COSV64749312; called by muse, mutect2, varscan2
- BRWD3 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.265); catalogued as COSV64750004; called by muse, mutect2, varscan2
- BSPH1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs966606956, COSV61223763; called by muse, varscan2
- BTBD8 | c.3251T>C p.F1084S (on ENST00000636805 / NM_001376131.1; = p.F571S on NM_015237.4) | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV64884133; called by muse, mutect2, varscan2
- BTBD8 | c.4828C>T p.R1610W (on ENST00000636805 / NM_001376131.1; = p.R1097W on NM_015237.4) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs778498972; called by muse, varscan2
- BTN2A2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as rs181037825; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, varscan2
- BTN3A3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs138755245; called by muse, mutect2, varscan2
- BUB1B | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 119/392 reads (30%) | catalogued as COSV55012352; called by muse, mutect2, varscan2
- BUB1B | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349349252, COSV99807268; called by muse, mutect2, varscan2
- C10orf120 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs189569073, COSV61492374; called by muse, mutect2, varscan2
- C11orf65 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs963242248; called by muse, mutect2, varscan2
- C12orf40 | c.1656G>T p.E552D | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV61130021; called by muse, mutect2, varscan2
- C12orf56 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs747742410; called by muse, mutect2, varscan2
- C14orf39 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs772448276; called by mutect2, varscan2
- C14orf39 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV58783372; called by muse, varscan2
- C16orf71 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs759601408; called by muse, mutect2, varscan2
- C17orf58 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as rs368145364; called by muse, mutect2, varscan2
- C19orf54 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 43/343 reads (13%) | catalogued as rs980827592; called by muse, mutect2, varscan2
- C1orf35 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs200591677; called by muse, mutect2, varscan2
- C1orf68 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.658); catalogued as rs571448810, COSV100908919; called by muse, mutect2, varscan2
- C1orf87 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV100967009; called by muse, mutect2, varscan2
- C1orf94 | c.1083G>T p.Q361H (on ENST00000488417 / NM_001134734.2; = p.Q171H on NM_032884.5) | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV64913356; called by muse, mutect2
- C20orf202 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as rs866769135, COSV68763909; called by muse, mutect2, varscan2
- C22orf42 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); catalogued as rs202224361; called by muse, mutect2, varscan2
- C2CD4A | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62789244; called by muse, mutect2, varscan2
- C2orf16 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV68646979; called by muse, varscan2
- C2orf16 | c.1888A>C p.N630H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV62675307; called by muse, mutect2, varscan2
- C2orf16 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs768227348, COSV100820845; called by muse, mutect2, varscan2
- C2orf16 | c.3627G>T p.K1209N | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62675729; called by muse, mutect2, varscan2
- C2orf49 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs1332346721, COSV51527370, COSV51527386; called by muse, mutect2, varscan2
- C2orf73 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58312064; called by muse, mutect2, varscan2
- C3 | c.4390C>T p.H1464Y | Missense Mutation (SNP) | VAF 71/334 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CM131620; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 143/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by muse, mutect2, varscan2
- C3orf20 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV53789172; called by muse, varscan2
- C4BPA | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as rs1366967873, COSV65535824, COSV65537022; called by muse, mutect2, varscan2
- C5orf22 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV104413592; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, varscan2
- C6orf58 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61667248; called by muse, mutect2, varscan2
- C6orf58 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV100315005; called by muse, mutect2, varscan2
- C7 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761703740, COSV57473318; called by muse, mutect2, varscan2
- C7orf26 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as rs755583704, COSV60418881; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, mutect2, varscan2
- C9orf135 | c.587G>T p.R196I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021086964; called by muse, mutect2, varscan2
- C9orf43 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs538217577, COSV55912476; called by muse, varscan2
- CA14 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs782689951, COSV99354469; called by muse, mutect2, varscan2
- CAB39L | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as rs373312261, COSV61716907; called by muse, mutect2, varscan2
- CABCOCO1 | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764156557, COSV57591674; called by mutect2, varscan2
- CABCOCO1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV57592045; called by muse, mutect2, varscan2
- CABIN1 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs140966977; called by muse, mutect2, varscan2
- CABS1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs925260963; called by muse, mutect2, varscan2
- CACNA1A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 17/232 reads (7%) | catalogued as rs886042230, COSV64194925; called by muse, mutect2
- CACNA1B | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs866214887, COSV53122014; called by muse, mutect2, varscan2
- CACNA1C | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59709919; called by muse, mutect2
- CACNA1E | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs369308237; called by muse, mutect2, varscan2
- CACNA1E | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 23/202 reads (11%) | catalogued as COSV62389043; called by muse, mutect2, varscan2
- CACNA1H | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747178657, COSV61986809; called by muse, mutect2
- CACNA1H | c.5161C>T p.R1721C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778448413; called by muse, mutect2, varscan2
- CACNA1S | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 180/545 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV62935975; called by muse, mutect2, varscan2
- CACNA1S | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 139/479 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62938672, COSV62939252; called by muse, mutect2, varscan2
- CACNB2 | c.785G>T p.R262I (on ENST00000324631 / NM_201596.3; = p.R207I on NM_000724.4) | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs754892849, COSV56611627; called by muse, mutect2, varscan2
- CACNG5 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV99400583; called by muse, mutect2, varscan2
- CALML4 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV100682811; called by muse, varscan2
- CALR | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs750961102, COSV100330677; called by muse, mutect2, varscan2
- CAMK1D | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs202177332, COSV66610725; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by muse, mutect2, varscan2
- CAMK2B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 28/391 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51664320; called by muse, mutect2
- CAMK2B | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs745930853, COSV51663383; called by muse, mutect2, varscan2
- CAMKK1 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as rs745519128, COSV99340605; called by muse, mutect2, varscan2
- CAMSAP1 | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762421052; called by muse, mutect2, varscan2
- CAMSAP1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs781626434, COSV56719297; called by muse, mutect2
- CAMTA1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs745719073, COSV57885227; called by muse, mutect2, varscan2
- CAMTA2 | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61833253; called by muse, mutect2, varscan2
- CAP1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 82/235 reads (35%) | catalogued as COSV61223935; called by muse, mutect2, varscan2
- CAP2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200559179, COSV57729499; called by muse, mutect2, varscan2
- CAPN3 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.443); catalogued as rs1219356790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPS2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs771352102, COSV60825021; called by muse, mutect2, varscan2
- CARD11 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67803459; called by muse, mutect2, varscan2
- CARMIL3 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.867); catalogued as rs1185826163; called by muse, mutect2, varscan2
- CARS2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs753936012, COSV57284437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASC3 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV104390865; called by muse, mutect2
- CASD1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51974004; called by muse, mutect2, varscan2
- CASP12 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65258992; called by muse, mutect2, varscan2
- CASP12 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs564091554, COSV100998306; called by muse, mutect2, varscan2
- CASP14 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as COSV55664907; called by muse, mutect2, varscan2
- CASP5 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829553; called by muse, mutect2, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, mutect2, varscan2
- CASP8AP2 | c.1531T>G p.L511V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as rs976828600; called by muse, mutect2, varscan2
- CASP8AP2 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767875273; called by muse, mutect2, varscan2
- CASP9 | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV61601188, COSV61602073; called by muse, mutect2, varscan2
- CAT | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 164/509 reads (32%) | catalogued as rs764544557; called by muse, mutect2, varscan2
- CATSPER1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 164/573 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs773724360; called by muse, mutect2, varscan2
- CATSPER2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 111/358 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as rs1372991382; called by muse, mutect2, varscan2
- CATSPERE | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1169062459; called by muse, mutect2, varscan2
- CATSPERE | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1268695029, COSV63676166; called by muse, mutect2, varscan2
- CBFA2T2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100656568; called by muse, mutect2, varscan2
- CBFA2T2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442534272, COSV60797089; called by muse, varscan2
- CBLL1 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56028453, COSV99755862; called by muse, mutect2, varscan2
- CBLL2 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60369345; called by muse, mutect2, varscan2
- CBLL2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257570318, COSV60368932; called by muse, mutect2, varscan2
- CBX2 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs782333644; called by muse, mutect2, varscan2
- CBX7 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1415800550, COSV53359053; called by muse, mutect2, varscan2
- CC2D2A | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as rs749997192, COSV67502420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308578865, COSV56274352; called by muse, mutect2, varscan2
- CCAR1 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV56267144; called by muse, varscan2
- CCDC105 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 122/220 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as rs1489552270, COSV99479928; called by muse, mutect2, varscan2
- CCDC105 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1444305809; called by muse, mutect2, varscan2
- CCDC110 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100293655; called by muse, mutect2, varscan2
- CCDC112 | c.82A>C p.N28H | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867834923; called by muse, mutect2, varscan2
- CCDC142 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as rs372963574; called by muse, mutect2, varscan2
- CCDC144A | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs199644397; called by muse, mutect2, varscan2
- CCDC148 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51757795; called by muse, mutect2, varscan2
- CCDC158 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs539971875, COSV66355611; called by muse, mutect2, varscan2
- CCDC166 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as rs781940688; called by muse, mutect2, varscan2
- CCDC168 | c.19196C>T p.T6399M | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs565198850; called by muse, mutect2, varscan2
- CCDC168 | c.6387C>A p.F2129L | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV101468943; called by muse, mutect2, varscan2
- CCDC17 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51969334, COSV51972039; called by muse, mutect2, varscan2
- CCDC170 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as rs751935416, COSV99498037; called by muse, mutect2, varscan2
- CCDC180 | c.147A>G p.I49M | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100826669; called by muse, mutect2, varscan2
- CCDC180 | c.3281C>T p.S1094L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs577764829; called by muse, mutect2, varscan2
- CCDC182 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1324456414; called by muse, mutect2, varscan2
- CCDC191 | c.1999C>A p.Q667K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99878007; called by muse, mutect2, varscan2
- CCDC28B | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs535125110, COSV52208047; called by muse, mutect2, varscan2
- CCDC42 | c.495C>T p.F165= | Splice Region (SNP) | VAF 24/142 reads (17%) | catalogued as rs752538761, COSV99549780; called by muse, mutect2
- CCDC47 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150438042, COSV99854043; called by muse, mutect2, varscan2
- CCDC62 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 20/158 reads (13%) | catalogued as rs757192126, COSV53433133; called by muse, mutect2, varscan2
- CCDC62 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754383945, COSV53437513; called by muse, mutect2, varscan2
- CCDC66 | c.2719C>T p.R907* (on ENST00000394672 / NM_001353147.1; = p.R873* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as rs374852204; called by mutect2, varscan2
- CCDC68 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61603293; called by muse, mutect2, varscan2
- CCDC68 | c.623G>T p.R208I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV61604050; called by muse, mutect2
- CCDC73 | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs377693069, COSV104406438; called by muse, varscan2
- CCDC74A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs141323157; called by muse, mutect2, varscan2
- CCDC8 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 138/231 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV56773319; called by muse, mutect2, varscan2
- CCDC81 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1379158275, COSV53577916; called by muse, mutect2, varscan2
- CCDC81 | c.1423G>T p.D475Y (on ENST00000445632 / NM_001156474.2; = p.D385Y on NM_021827.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53579324; called by muse, mutect2, varscan2
- CCDC82 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768645326, COSV53595144; called by muse, mutect2, varscan2
- CCDC82 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 21/159 reads (13%) | catalogued as rs749491502; called by muse, mutect2, varscan2
- CCDC82 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753336168, COSV53591996; called by muse, mutect2, varscan2
- CCDC88A | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs769621745, COSV55069328; called by muse, mutect2, varscan2
- CCDC91 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774693971, COSV60347182; called by muse, mutect2, varscan2
- CCKAR | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs756780999, COSV55160991; called by muse, varscan2
- CCL5 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs779249457; called by muse, mutect2, varscan2
- CCN2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63466512; called by muse, mutect2, varscan2
- CCNB3 | c.3713G>A p.R1238Q | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1447299051, COSV52072736, COSV52081222; called by muse, mutect2, varscan2
- CCND3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 83/543 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as COSV65913381; called by muse, mutect2, varscan2
- CCNJL | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as rs906026584; called by muse, mutect2, varscan2
- CCNQ | c.342C>A p.F114L | Missense Mutation (SNP) | VAF 181/555 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52345809; called by muse, mutect2, varscan2
- CCP110 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768073766; called by muse, mutect2, varscan2
- CCP110 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as COSV66816738, COSV66817006; called by muse, mutect2, varscan2
- CCR2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 48/153 reads (31%) | catalogued as rs1454368903, COSV52747915; called by muse, mutect2, varscan2
- CCR3 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 62/156 reads (40%) | catalogued as rs754911047, COSV62462585; called by muse, mutect2, varscan2
- CCRL2 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62193452; called by muse, mutect2, varscan2
- CCSAP | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as rs1376791996; called by muse, mutect2, varscan2
- CCT6A | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs766996972, COSV51906806; called by muse, mutect2, varscan2
- CD101 | c.2254C>A p.H752N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); catalogued as COSV56721547; called by muse, mutect2, varscan2
- CD163 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 116/376 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV63129992; called by muse, varscan2
- CD180 | c.1204A>C p.N402H | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56518912; called by muse, mutect2, varscan2
- CD180 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV56520364; called by muse, mutect2, varscan2
- CD180 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV56517225; called by muse, mutect2, varscan2
- CD207 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV69652747; called by muse, mutect2, varscan2
- CD209 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 35/408 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs763770706; called by muse, mutect2
- CD209 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 320/711 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV52659939; called by muse, mutect2, varscan2
- CD22 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 99/365 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV99323548; called by muse, mutect2, varscan2
- CD248 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs757640463, COSV100256688; called by muse, mutect2, varscan2
- CD40LG | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 20/171 reads (12%) | catalogued as CM960252; called by muse, mutect2, varscan2
- CD46 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV59731196; called by muse, mutect2, varscan2
- CD72 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571917444; called by muse, mutect2, varscan2
- CDC123 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55400458; called by muse, mutect2, varscan2
- CDC20 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60521638; called by muse, mutect2, varscan2
- CDC27 | c.1173G>A p.E391= | Splice Region (SNP) | VAF 10/58 reads (17%) | catalogued as rs544208833; called by muse, mutect2, varscan2
- CDC37 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs757086543; called by muse, mutect2, varscan2
- CDC73 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV66465084; called by muse, mutect2
- CDC73 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 90/273 reads (33%) | catalogued as COSV66465810; called by muse, mutect2, varscan2
- CDCA2 | c.1727C>A p.S576Y | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149619070; called by muse, mutect2, varscan2
- CDH10 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100050450; called by muse, mutect2
- CDH11 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs551918062, COSV51778517; called by muse, mutect2, varscan2
- CDH12 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66443822; called by muse, mutect2
- CDH16 | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233615; called by muse, mutect2, varscan2
- CDH18 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV56905362; called by muse, mutect2, varscan2
- CDH19 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs754638138, COSV50958036; called by muse, mutect2
- CDH26 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs1479719725, COSV54847357; called by muse, mutect2, varscan2
- CDH5 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | catalogued as rs373144857; called by muse, mutect2, varscan2
- CDH8 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54856958; called by muse, mutect2, varscan2
- CDH9 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs141440884; called by muse, varscan2
- CDHR3 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1013945866, COSV100488314; called by muse, mutect2, varscan2
- CDK17 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV99702616; called by muse, mutect2, varscan2
- CDK5RAP2 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV62578044; called by muse, varscan2
- CDK7 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1056698472, COSV56511913; called by muse, mutect2, varscan2
- CDKL5 | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV66113580; called by muse, varscan2
- CDKL5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 66/519 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV101184378; called by muse, varscan2
- CDON | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs761054118, COSV54995637; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDRT1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs764342527, COSV55410733; called by muse, mutect2, varscan2
- CEACAM5 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as rs1555815452; called by muse, mutect2, varscan2
- CELF3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778026308, COSV51881488; called by muse, mutect2, varscan2
- CELSR2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54771582; called by muse, mutect2, varscan2
- CELSR2 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs1282271728; called by muse, mutect2, varscan2
- CENPA | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 46/161 reads (29%) | catalogued as COSV51982330; called by muse, mutect2, varscan2
- CENPC | c.1724C>A p.T575N | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs769332746; called by muse, mutect2, varscan2
- CENPF | c.6626G>A p.R2209K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV100872025; called by muse, mutect2, varscan2
- CENPM | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53245763; called by muse, mutect2, varscan2
- CENPQ | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1417751717; called by muse, mutect2, varscan2
- CEP120 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs780184609; called by muse, mutect2, varscan2
- CEP126 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as COSV54827338, COSV54831336; called by muse, mutect2, varscan2
- CEP128 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs778575359; called by muse, mutect2, varscan2
- CEP135 | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as rs186530606, COSV57258576; called by muse, mutect2, varscan2
- CEP152 | c.2129G>T p.R710I | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs1022617230, COSV57857950; called by muse, mutect2, varscan2
- CEP192 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100382467; called by muse, mutect2, varscan2
- CEP250 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100699169, COSV61169227; called by muse, mutect2, varscan2
- CEP55 | c.1163G>T p.R388I | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV101016761; called by muse, mutect2, varscan2
- CEP95 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as rs782529622; called by muse, mutect2, varscan2
- CERKL | c.1012G>A p.A338T (on ENST00000339098 / NM_001030311.2; = p.A312T on NM_201548.5) | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs190967171; called by muse, mutect2, varscan2
- CERS3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as COSV52567227, COSV52568348; called by muse, mutect2, varscan2
- CES1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs1176989930, COSV62086812; called by muse, mutect2, varscan2
- CES4A | c.125A>C p.H42P | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs756940311; called by muse, mutect2, varscan2
- CETN1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs760929013, COSV59121106, COSV59121251; called by muse, mutect2, varscan2
- CETN1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59121006; called by muse, mutect2, varscan2
- CETP | c.846C>A p.F282L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.043); catalogued as COSV52363582, COSV52363995; called by muse, varscan2
- CETP | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs756231195; called by muse, varscan2
- CFAP157 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs764305353; called by muse, mutect2, varscan2
- CFAP161 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs762300584; called by muse, mutect2, varscan2
- CFAP206 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781384108, COSV51532655; called by muse, mutect2, varscan2
- CFAP300 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101462489; called by muse, mutect2, varscan2
- CFAP43 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.169); catalogued as rs759954879, COSV53377720, COSV99530439; called by muse, mutect2, varscan2
- CFAP54 | c.3209G>T p.R1070I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1395849963; called by muse, mutect2, varscan2
- CFAP54 | c.5107G>T p.E1703* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV61570903; called by muse, mutect2, varscan2
- CFAP54 | c.6602A>C p.K2201T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV61574697; called by muse, mutect2, varscan2
- CFAP57 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 16/141 reads (11%) | catalogued as rs1475856420; called by muse, mutect2, varscan2
- CFAP58 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as COSV57211244; called by muse, mutect2, varscan2
- CFAP58 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV63836579; called by muse, mutect2, varscan2
- CFAP61 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs760689597, COSV55620168, COSV55632747; called by muse, mutect2, varscan2
- CFAP65 | c.5164A>G p.K1722E | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as rs1271411668; called by muse, mutect2, varscan2
- CFAP70 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as COSV60284097; called by muse, mutect2, varscan2
- CFAP70 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60281974; called by muse, mutect2, varscan2
- CFAP74 | c.3792G>T p.K1264N | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs763696117; called by muse, mutect2, varscan2
- CFHR2 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as COSV66380750, COSV66381328; called by muse, mutect2
- CFHR4 | c.617C>A p.S206Y (on ENST00000367416 / NM_001201551.2; = p.S207Y on NM_001201550.3) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52227769, COSV99259763; called by muse, mutect2
- CFTR | c.1621C>A p.L541I | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.608); catalogued as COSV50073317; called by muse, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, varscan2
- CGB3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.375); catalogued as rs1253856733; called by mutect2, varscan2
- CHD5 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1363216674, COSV52414830; called by muse, mutect2, varscan2
- CHD5 | c.2601G>T p.K867N | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as COSV52417023; called by muse, mutect2, varscan2
- CHD7 | c.5621C>A p.S1874Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV71108610; called by muse, mutect2, varscan2
- CHD9 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs534624677, COSV54607877, COSV54608971; called by muse, mutect2, varscan2
- CHL1 | c.2071G>A p.E691K (on ENST00000397491 / NM_001253387.1; = p.E707K on NM_006614.4) | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.12); catalogued as rs771423332, COSV56593907; called by muse, mutect2, varscan2
- CHM | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV63303102; called by muse, mutect2, varscan2
- CHMP2A | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as rs776185223; called by muse, mutect2, varscan2
- CHMP2B | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 39/234 reads (17%) | catalogued as rs780237778; called by muse, mutect2, varscan2
- CHMP6 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs775200526, COSV57326978; called by muse, mutect2, varscan2
- CHPF | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs527954030, COSV60534174; called by mutect2, varscan2
- CHRM3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168092147; called by muse, mutect2
- CHRNA10 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs773351290; called by muse, mutect2, varscan2
- CHRNA3 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs781008848, COSV100468559; called by mutect2, varscan2
- CHRNA6 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV52379058, COSV99373095, COSV99373303; called by muse, mutect2
- CHRNA9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758485973, COSV59575615; called by muse, mutect2, varscan2
- CHRNB1 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53439634, COSV99548509; called by muse, mutect2, varscan2
- CHRND | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.119); catalogued as COSV51333075; called by muse, mutect2, varscan2
- CHST12 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 142/291 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs746228708, COSV51674381; called by muse, mutect2, varscan2
- CHUK | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV64918054; called by muse, mutect2, varscan2
- CIITA | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.361); catalogued as rs759293478, COSV60854841; called by muse, mutect2, varscan2
- CILP | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs780209937, COSV56026633; called by muse, mutect2, varscan2
- CIZ1 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs757979620, COSV52972065; called by muse, mutect2, varscan2
- CKAP2L | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148836584; called by muse, mutect2, varscan2
- CKAP5 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100370862; called by muse, mutect2
- CLASP1 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV99754098; called by muse, mutect2
- CLCN5 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM139671; called by muse, mutect2, varscan2
- CLCN5 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1373322324, COSV100259774; called by muse, mutect2
- CLEC16A | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1254916058, COSV68499404; called by muse, mutect2, varscan2
- CLEC19A | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV71854365; called by muse, mutect2
- CLEC1B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237872141, COSV53725393, COSV53726050; called by muse, mutect2
- CLEC2B | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 39/302 reads (13%) | catalogued as rs771674688, COSV57308579, COSV99947008; called by muse, mutect2, varscan2
- CLEC5A | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as COSV69397984; called by muse, mutect2, varscan2
- CLGN | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs563971370, COSV100346735; called by muse, varscan2
- CLIC2 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.201); catalogued as COSV100425503; called by muse, varscan2
- CLINT1 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV51628851; called by muse, mutect2, varscan2
- CLPTM1 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61612936; called by muse, mutect2, varscan2
- CLSPN | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52048832; called by muse, mutect2, varscan2
- CMIP | c.735C>A p.F245L (on ENST00000537098 / NM_198390.2; = p.F151L on NM_030629.3) | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV101220879; called by muse, mutect2
- CMIP | c.896C>T p.A299V (on ENST00000537098 / NM_198390.2; = p.A205V on NM_030629.3) | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.449); catalogued as rs1018468079, COSV101220889; called by muse, mutect2, varscan2
- CMPK2 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 48/312 reads (15%) | catalogued as COSV99878783; called by muse, mutect2, varscan2
- CMTR2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462027522; called by muse, mutect2, varscan2
- CNGA3 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs757155005; called by muse, mutect2, varscan2
- CNKSR2 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54252751; called by muse, mutect2, varscan2
- CNKSR2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1569272190, COSV54262591; called by muse, mutect2
- CNNM2 | c.2351C>A p.S784Y | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1218026306, COSV100881797, COSV64001480; called by muse, mutect2, varscan2
- CNNM4 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65660182; called by muse, mutect2, varscan2
- CNOT1 | c.4432C>T p.R1478C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1567396193; called by muse, mutect2
- CNOT4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs1308899779, COSV59651637; called by muse, mutect2, varscan2
- CNR1 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.048); catalogued as COSV62986310, COSV62990769; called by muse, mutect2, varscan2
- CNTD1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs753249329, COSV59312762; called by muse, mutect2
- CNTLN | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1010581392, COSV52064040; called by muse, mutect2, varscan2
- CNTLN | c.1146+1G>T p.X382_splice | Splice Site (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52068069; called by muse, mutect2, varscan2
- CNTLN | c.2120G>T p.R707M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs1222075483; called by muse, mutect2, varscan2
- CNTN1 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61642536; called by muse, mutect2, varscan2
- CNTN4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.611); catalogued as rs779295042, COSV100639413, COSV61870385; called by muse, mutect2, varscan2
- CNTN4 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV61872648; called by muse, mutect2, varscan2
- CNTN6 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63186458; called by muse, mutect2, varscan2
- CNTN6 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.083); catalogued as rs1190851541, COSV100609560; called by muse, mutect2, varscan2
- CNTNAP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777035367, COSV100663349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP4 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56664361, COSV56688548; called by muse, mutect2, varscan2
- CNTNAP4 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 91/275 reads (33%) | catalogued as COSV100273632; called by muse, mutect2, varscan2
- CNTNAP4 | c.2964C>A p.F988L | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100271308; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 18/382 reads (5%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2
- CNTNAP5 | c.2243C>A p.T748N | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs201558367; called by muse, mutect2, varscan2
- CNTNAP5 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101444168; called by muse, mutect2
- CNTRL | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 9/188 reads (5%) | catalogued as rs1564271317, COSV99441472; called by muse, mutect2
- CNTROB | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs772562149; called by muse, mutect2, varscan2
- COBLL1 | c.3128A>C p.N1043T (on ENST00000392717; = p.N1005T on NM_014900.5) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV52071257; called by muse, mutect2, varscan2
- COL14A1 | c.3398G>A p.G1133D | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52869924; called by muse, mutect2, varscan2
- COL16A1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 138/395 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs757571546; called by muse, mutect2, varscan2
- COL17A1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 71/521 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs766539630, COSV62226972; called by muse, mutect2, varscan2
- COL21A1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV55155273; called by muse, mutect2, varscan2
- COL25A1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1233681099, COSV101211297; called by muse, mutect2, varscan2
- COL2A1 | c.4223A>C p.K1408T | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61529278; called by muse, mutect2, varscan2
- COL2A1 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 61/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs148350640, COSV61527431; called by muse, mutect2, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.444C>T p.P148= | Splice Region (SNP) | VAF 54/192 reads (28%) | catalogued as rs773871417, COSV100565222; called by muse, mutect2, varscan2
- COL5A1 | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs149212775, COSV65668143; called by muse, mutect2, varscan2
- COL5A2 | c.2507G>T p.R836L | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV66409358; called by muse, mutect2, varscan2
- COL5A3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs563109290, COSV53409530; called by muse, mutect2
- COL6A2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 103/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368064647, COSV56003126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781514010, COSV55082529; called by muse, mutect2, varscan2
- COL6A3 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs768050320, COSV55091677; called by muse, mutect2, varscan2
8,541 further variants in this file (5,800 protein-altering or splice-affecting, 1,708 silent, 1,033 other) are not listed here.
